Somatic mutation profile of tumor specimen TCGA-OR-A5L9-01A (aliquot TCGA-OR-A5L9-01A-11D-A29I-10) from TCGA case TCGA-OR-A5L9, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 53.5 years (19,526 days).
Specimen TCGA-OR-A5L9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cfb87eb-adb8-4def-859f-35cedc551c3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5L9-10B (Blood Derived Normal), aliquot TCGA-OR-A5L9-10B-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdad974f-5647-4759-be7a-8402455eaf23

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- G6PD | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 153/434 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs369603624; called by muse, mutect2, varscan2
- FBLN2 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.022); called by muse, mutect2
- HDAC6 | c.1953C>A p.H651Q | Missense Mutation (SNP) | VAF 187/446 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDRG2 | c.439G>C p.A147P (on ENST00000298687 / NM_001354570.1; = p.A133P on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WWP1 | c.1089T>G p.G363= | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
